Surgical pathology report (de-identified scan), TCGA case TCGA-68-7755, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-7755-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

SPECIMEN SUBMITTED:

Part A: BRONCHUS INTERMEDIUS
LYMPH NODE
Part B: RIGHT PNEUMONECTOMY
Part C: FIRST RIB
Part D: 10R
Part E: 11R
Part F: 12R
Part G: 4R
Part H: PERIPHRENIC LYMPH NODE
Part I: 7

Final Diagnosis

1. Bronchus intermedius lymph nodes, excision (A) - Invasive squamous cell carcinoma.
2. Right lung, pneumonectomy (B) - Invasive squamous cell carcinoma (see comment).
- Metastatic squamous cell carcinoma in peribronchial lymph nodes.
- Giant cell reaction to suture material consistent with prior surgery.
- Centrilobular emphysema.
- Adhered diaphragmatic skeletal muscle with no significant pathologic changes.
3. First rib, excision (C) - Bone with no significant pathologic changes.
4. Lymph nodes, 10R, 11R, 12R, 4R, periphrenic lymph node, #7, excision (D-I) - Lymph nodes; negative for neoplasm.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Tumor Location: Right hilum.

Tumor Size: 3 cm in greatest dimension.

Vascular Invasion: Negative

Lymphatic Invasion: Not identified.

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Not applicable.

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): p stage IIA (T1b N1 M0)

Intraoperative Diagnosis:

A. Positive for squamous cell carcinoma

B. Proximal bronchial margin, negative for malignancy

Clinical Diagnosis:

LUNG CA

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh for intraoperative consultation labeled "bronchus intermedius lymph node" is one tan-pink nodule consistent with a lymph node measuring 0.4 x 0.3 x 0.2 cm. It is entirely submitted for frozen section diagnosis as FSA1.

B. Received fixed is a specimen labeled "right pneumonectomy" is a right lung that weighs 329 grams, and measures 18 x 12.5 x 4 cm. The anatomy of the lung is distorted from a previous surgical procedure probably a middle lobectomy, as the middle lobe can not be identified. There is also a line of staples with adhesions from the previous procedure and this area is adhered to skeletal muscle that measures 4 x 6 cm. A firm white tumor measuring in greatest dimension 3 cm is present in the hilar bronchus, with multiple matted lymph nodes near it. The tumor is 1.5 cm from the bronchial margin. The remainder of the uninvolved lung parenchyma shows mucus plugging. There are multiple lymph nodes in the perihilar soft tissue. Representative sections are submitted as follows: B1 for frozen section true bronchial margin, B2 frozen section not true margin of bronchus, B3 bronchus adjacent to margin, B4 vascular margin, B5-B12 tumor entirely blocked in with lymph nodes, normal lung (black ink pleural surface), B13 upper lobe, B14 lower lobe, B15 adhered skeletal muscle, B16 one lymph node, B17 one lymph node, B18 four possible lymph nodes, B19 one lymph node.

C. Received fresh labeled "first rib" is a specimen consisting of three fragments of rib measuring in aggregate 16 x 1 x 1 cm. The bone is unremarkable. Representative section is submitted after decal in C1.

D. Received fresh on Telfa gauze labeled "10R" are three irregular segments of anthracotic nodules ranging in size from 0.1 to 0.7 cm in greatest dimension. The nodules are totally submitted as follows: C1 two nodules, C2 one nodule.

E. Received fresh on Telfa gauze labeled "11R" are multiple anthracotic nodules aggregating to 0.7 x 0.7 x 0.2 cm. The specimen is totally submitted in one cassette.

F. Received fresh on Telfa gauze labeled "12R" is a fragmented anthracotic nodule measuring 1 x 0.7 x 0.2 cm. The specimen is totally submitted in one cassette.

G. Received fresh on Telfa gauze labeled "4R" is an anthracotic nodule measuring 1.3 x 1.3 x 0.5 cm. The nodule is totally submitted in one cassette.

H. Received fresh on Telfa gauze labeled "paraphrenic lymph node" is an anthracotic nodule with attached adipose tissue measuring 1.5 x 1.0 x 0.4 cm. The nodule is totally submitted in one cassette.

I. Received fresh on Telfa gauze labeled "#7" is an anthracotic nodule with attached adipose tissue measuring 0.8 x 0.7 x 0.5 cm. The nodule is totally submitted in one cassette.

Source: NCI Genomic Data Commons file 33d26baa-a9d1-4fde-8b44-dd39da0a56ba (TCGA-68-7755.472F285D-D573-47AF-95C7-9C4B45FBAE40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).